Somatic mutation profile of tumor specimen TARGET-30-PASEJZ-01A (aliquot TARGET-30-PASEJZ-01A-01D) from TARGET case TARGET-30-PASEJZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.5 years (564 days).
Specimen TARGET-30-PASEJZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a89fee4-6779-48ef-b81a-2fefa4aa987e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASEJZ-10A (Blood Derived Normal), aliquot TARGET-30-PASEJZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b6416e6-e2eb-4ea6-815d-159fcea96bcf

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 33/100 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD2 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53967413; called by muse, mutect2, varscan2
- AXL | c.1634-1G>T p.X545_splice (on ENST00000301178 / NM_021913.5; = p.X536_splice on NM_001699.6) | Splice Site (SNP) | VAF 54/113 reads (48%) | catalogued as COSV56563684; called by muse, mutect2, varscan2
